Somatic mutation profile of tumor specimen TARGET-10-PAPZVI-09A (aliquot TARGET-10-PAPZVI-09A-01D) from TARGET case TARGET-10-PAPZVI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (867 days).
Specimen TARGET-10-PAPZVI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8150fd19-737b-486e-9d28-254b6aed5003.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZVI-10A (Blood Derived Normal), aliquot TARGET-10-PAPZVI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bda9b89-ff51-429a-acbc-07d534232241

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPAP1 | c.725C>A p.T242K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.519); catalogued as COSV61512420; called by muse, mutect2
- ZCCHC8 | c.1820G>T p.C607F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1245861835; called by muse, mutect2, varscan2
- ARID5B | c.2323C>A p.H775N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- DPEP2 | c.1207G>T p.V403L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2
- RNF144A | c.11C>A p.T4K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); called by muse, mutect2
- TMCC3 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- INVS | c.1407C>A p.I469= | Silent (SNP) | VAF 49/123 reads (40%) | called by muse, varscan2
- KSR2 | c.963C>T p.R321= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs1025244189, COSV60366545; called by mutect2, varscan2
- SOWAHC | c.888G>A p.K296= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, varscan2
- TBL2 | c.999G>T p.A333= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- GLRX | chr5:95824014 C>A | 5'Flank (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- NRG1 | c.401-10T>A | Intron (SNP) | VAF 34/104 reads (33%) | catalogued as COSV55165650; called by muse, varscan2
- PRKD1 | c.2434+3341T>A | Intron (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
